Somatic mutation profile of tumor specimen TCGA-DU-A5TW-01A (aliquot TCGA-DU-A5TW-01A-11D-A289-08) from TCGA case TCGA-DU-A5TW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 33.1 years (12,107 days).
Specimen TCGA-DU-A5TW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63885a4a-8e34-4549-93b8-f6155c5842ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A5TW-10A (Blood Derived Normal), aliquot TCGA-DU-A5TW-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf447f5e-0766-4340-b317-c38a0ff0fba7

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/64 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.994-1G>C p.X332_splice | Splice Site (SNP) | VAF 30/38 reads (79%) | hotspot (GDC flag); catalogued as rs587782272, CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV60485642; called by muse, mutect2, varscan2
- ANKRD17 | c.852+2T>C p.X284_splice | Splice Site (SNP) | VAF 27/81 reads (33%) | catalogued as COSV58219058; called by muse, mutect2, varscan2
- ARID5A | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs760637606, COSV62591027; called by muse, mutect2, varscan2
- ATG2A | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV65966483; called by muse, mutect2, varscan2
- BRS3 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV65710906; called by muse, mutect2
- DDX27 | c.93C>G p.N31K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV65629516; called by muse, mutect2, varscan2
- DDX31 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766609776, COSV60135310; called by muse, mutect2
- DMD | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs765584669, COSV55866292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.3943G>A p.E1315K | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs753397685, COSV54219463; called by muse, mutect2, varscan2
- EPPK1 | c.6578C>T p.T2193M | Missense Mutation (SNP) | VAF 100/423 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs782320865, COSV73261084; called by muse, mutect2, varscan2
- EVI2B | c.570T>G p.S190R | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV58363872, COSV58364958; called by muse, mutect2
- FBN3 | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs201458670, COSV54458826; called by muse, mutect2
- HSPA9 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 17/159 reads (11%) | catalogued as COSV51864215; called by muse, mutect2, varscan2
- IL1RAPL2 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61153375; called by muse, mutect2, varscan2
- JADE1 | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV56905487; called by muse, mutect2, varscan2
- JAKMIP1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV51528357; called by muse, mutect2
- LMOD2 | c.674C>A p.T225K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV71755614; called by muse, mutect2, varscan2
- MGAT3 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1255865821, COSV100361821, COSV57865078; called by muse, mutect2, varscan2
- MUC16 | c.34760C>T p.T11587M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs763078522, COSV67455495; called by muse, mutect2, varscan2
- MUC17 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 82/1048 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs200376693; called by muse, mutect2
- MUC7 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV59218136; called by muse, varscan2
- MYH8 | c.3416G>A p.R1139H | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV67963629, COSV67968113; called by muse, mutect2, varscan2
- NCK1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 16/118 reads (14%) | catalogued as COSV56637012, COSV99999376; called by muse, mutect2, varscan2
- NLN | c.2036T>C p.M679T | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs149642804, COSV66765636; called by muse, mutect2, varscan2
- NLRP2 | c.2441C>T p.T814M | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as rs370914730; called by muse, mutect2, varscan2
- NOC2L | c.1444A>G p.M482V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58987127; called by muse, mutect2, varscan2
- PBXIP1 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs200785325; called by muse, mutect2
- RENBP | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV60071585; called by muse, mutect2
- RNF8 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV57721093; called by muse, mutect2, varscan2
- SGK2 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs1218495423, COSV58312940; called by muse, mutect2
- SUGP1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs765038141, COSV55924110; called by muse, mutect2
- SUPV3L1 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV62845156; called by muse, mutect2, varscan2
- SYTL4 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs760447949, COSV52167221; called by muse, mutect2, varscan2
- TEAD1 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57563541; called by muse, mutect2
- TENM3 | c.2684C>T p.T895I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV69305553; called by muse, mutect2, varscan2
- TRUB1 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV53929264; called by muse, mutect2, varscan2
- ADH1C | c.1071_1073del p.N357_E358delinsK | In Frame Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel
- ATRX | c.2912_2915del p.K971Tfs*31 | Frame Shift Del (DEL) | VAF 78/202 reads (39%) | called by pindel, varscan2
- KATNAL2 | c.920_921del p.V307Gfs*3 (on ENST00000356157 / NM_001353899.1; = p.V235Gfs*3 on NM_031303.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by pindel, varscan2
- ACCS | c.72G>T p.L24= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV55457964; called by muse, mutect2, varscan2
- CCDC8 | c.666C>T p.G222= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1385856223, COSV56773021; called by muse, mutect2, varscan2
- CHST1 | c.255C>T p.D85= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV57323234; called by muse, mutect2, varscan2
- CPT1C | c.309G>A p.G103= | Silent (SNP) | VAF 21/239 reads (9%) | catalogued as COSV54918811; called by muse, mutect2
- GPR4 | c.150C>T p.N50= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV59916756, COSV59917393, COSV59917617; called by muse, mutect2, varscan2
- NEU4 | c.36C>T p.L12= (on ENST00000391969 / NM_001167602.3; = p.L24= on NM_080741.4) | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1479706252, COSV57990164; called by muse, mutect2, varscan2
- NFYB | c.276G>A p.E92= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV53529557; called by muse, mutect2, varscan2
- PRR19 | c.882G>A p.T294= | Silent (SNP) | VAF 11/192 reads (6%) | catalogued as rs1190805602, COSV56624898; called by muse, mutect2
- SLCO1B3 | c.1074C>T p.Y358= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs145036538; called by muse, mutect2, varscan2
- SVEP1 | c.7128T>C p.C2376= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV52838413; called by muse, mutect2, varscan2
- AP001042.1 | n.2508G>A | RNA (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
